Surgical pathology report (de-identified scan), TCGA case TCGA-VN-A943, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site NCI Urologic Oncology Branch, specimen TCGA-VN-A943-01A (Primary Tumor).

[page 1 of 3]
Patient Results

Page 1 of 3

Gender: Male	Birth Date:	Admit Date:
Attending:	Admit Protocol:	Age:
		Location:

Surgical Pathology	Final Results
--------------------	---------------

Surgical Pathology
CASE NUMBER:
DIAGNOSIS:

Final

- Prostate, radical prostatectomy:
* Adenocarcinoma, Gleason score 8 (4 + 4), involving 40% of the left lobe and 25% of the right lobe. Perineural invasion present.
No seminal vesicle or extracapsular invasion seen.
* Margins of resection are free of tumor. See Note.
- Seminal vesicle, left, portion of, radical prostatectomy: Seminal vesicle, no tumor seen.
- Lymph node, obturator, right, radical prostatectomy: Three lymph nodes, no tumor seen (0/3).
- Lymph node, obturator, left, packet, radical prostatectomy: Seven lymph nodes, no tumor seen (0/7).
- Lymph node and fat, over anterior prostate, radical prostatectomy: Fibroadipose tissue, no tumor seen.

ICD-O-3
Adenocarcinoma NOS
8140/3
Site: Prostate NOS
861.9
11/21/14

NOTE:

CAP Cancer Protocol:
Procedure: Radical prostatectomy
Prostate Size
Weight: 49.5 g
Size: 5.1 x 3.5 x 4.5 cm
Lymph Node Sampling: Pelvic lymph node dissection
Histologic Type: Adenocarcinoma (acinar, not otherwise specified)
Histologic Grade
Gleason Pattern
Primary Pattern: Grade 4
Secondary Pattern: Grade 4
Total Gleason Score: 8
Tumor Quantitation
Proportion (percentage) of prostate involved by tumor: 40% of left lobe, 25% of right lobe.
Extraprostatic Extension: Not identified
Seminal Vesicle Invasion: Not identified
Margins : Margins uninvolved by invasive carcinoma
Treatment Effect on Carcinoma: Not identified
Lymph-Vascular Invasion: Not identified
Perineural Invasion: Present
Pathologic Staging (pTNM)
Primary Tumor (pT)
pT2c: Bilateral disease
Regional Lymph Nodes (pN)
pN0: No regional lymph node metastasis
Number of Lymph Nodes Examined
Specify: 10
Number of Lymph Nodes Involved
Specify: 0

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

Requested By:

Do not file in Medical Record

[page 2 of 3]
Gender: Male	Birth Date:	Admit Protocol:
Admit Protocol:	Admit Protocol:	Age:
		Location:

Surgical Pathology [OrderID: _____]	Final Results
-------------------------------------	---------------

Distant Metastasis (pM): Not applicable
Additional Pathologic Findings: None identified
Ancillary Studies: Not performed

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the . They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Brief Clinical History: prostate cancer Specimen Taken For Protocol:
Yes Allocate Order to Protocol:

PROCEDURE: Operative Findings: prostate and lymph nodes
Post-Operative Diagnosis:
prostate cancer Pre-Operative Diagnosis: prostate cancer

SPECIMENS SUBMITTED: 1. PROSTATE
2. SEMINAL VESICLE, LEFT
3. OBTURATOR LYMPH NODE(S), Right
4. OBTURATOR LYMPH NODE(S), Left
5. LYMPH NODES, Fat over anterior prostate

GROSS DESCRIPTION: Received are 5 freshly submitted specimens each labeled " " and further specified as follows:

1. "Prostate" consists of a prostatectomy specimen weighing 49.5 grams with the following measurements:
Left to right: 5.1 cm,
Anterior-posterior: 3.5 cm,
Apex-base: 4.5 cm,
Left seminal vesicles: 3.1 x 1.2 x 0.8 cm,
Left vas deferens: 3.8 cm in length x 0.4 cm in diameter,
Right seminal vesicles: 4.2 x 1.6 x 0.7 cm,
Right vas deferens: 4.0 cm in length x 0.6 cm in diameter.

The prostate is follows: Urethra in yellow, anterior 1/3 in black, right posterior 2/3 in blue, and left posterior 2/3 in red. Gross photographs are taken.

One cut is made revealing a tan nodular cut surface and yellow hard area measuring approximately 1.5 x 1 cm. Approximately 1 x 0.8 x 0.2 cm of tumor left the apex and approximately 1 x 0.8 x 0.2 cm of normal-appearing prostatic tissue from the right apex are procured for the by and documented by on at

Received in Surgical Pathology is a specimen matching the above description. The prostate is serially sectioned from apex to base

[page 3 of 3]
Gender: Male	Birth Date:	Admit Protocol:
Admit Protocol:	Admit Protocol:	Age:
		Location:

Surgical Pathology	Final Results
---------------------------	----------------------

using a custom-fabricated mold. Summary of sections is as follows:
1A-H: Serially sectioned prostate from apex to base, entirely submitted

1I-L: Left seminal vesicles and vas deferens, entirely submitted
1K-O: Right seminal vesicles and vas deferens, entirely submitted

2. "Portion of left seminal vesicles" is a single unoriented tan soft tissue fragment with two surgical clips in place at either end, overall measuring 0.9 x 0.5 x 0.2 cm. The clips are removed and the tissues are entirely submitted in white cassette

3. "Right obturator lymph node" is a single yellow lobulated adipose tissue fragment, 5.5 x 2.5 x 0.7 cm, incorporating a single elongated tan rubbery candidate lymph node, 3.6 x 1 x 0.6 cm. The candidate lymph node is bisected revealing a partially fat replaced cut surface. The specimen is submitted as follows:

#3A 1 candidate lymph node, sectioned.

#3B remainder of the specimen comprised largely of adipose tissue

4. "Left obturator lymph node packet" are 2 yellow lobulated fatty tissue fragments, in the aggregate 5.5 x 2.5 x 0.7 cm incorporating 3 tan rubbery candidate lymph nodes ranging from 1 to 1.9 cm. The specimen is entirely submitted as follows:

#4A 1 bisected candidate lymph node

#4B 2 smaller intact candidate lymph nodes

#4C remainder of the specimen largely comprised of adipose tissues

5. "Fat and lymph nodes over anterior prostate" are 6 yellow lobulated adipose tissue fragments ranging from 0.9 to 2.4 cm in greatest dimensions and in the aggregate 2.4 x 2.4 x 0.8 cm. The tissues are palpated and obvious macroscopic candidate lymph nodes are not identified. All of the fragments are submitted in white cassettes A-5D.

Gross Description dictated by .

No consultants

Accessioned:

Final Report Signed Out:

<Resident Signature>

<Sign Out Dr. Signature>

Date Report Signed:

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act.

Requested By:

Source: NCI Genomic Data Commons file 77c1a298-4003-4642-acd6-af5053b05ee1 (TCGA-VN-A943.089DAFFA-4FD5-4219-9C79-17F6E5405784.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).